Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4335, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4335-01A (Primary Tumor).

[page 1 of 2]
Clinical Diagnosis & History:

with left renal and adrenal mass (+) bx renal cell ca.

Specimens Submitted:

1: SP: Lt. kidney & adrenal gland

DIAGNOSIS:

- 1) KIDNEY AND ADRENAL GLAND, LEFT; EXCISION:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE III/IV. THE TUMOR GREATEST DIAMETER IS 5.5 CM. THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA. NO INVASION OF THE RENAL VEIN IS IDENTIFIED. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE NON-NEOPLASTIC KIDNEY SHOWS INTERSTITIAL FIBROSIS, AND CHRONIC INFLAMMATION. THE ADRENAL GLAND IS INVOLVED BY METASTATIC CARCINOMA MEASURING 10.5 CM IN GREATEST DIAMETER. VASCULAR INVASION PRESENT IN THE RENAL SINUS.

Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	
	RECUT	

- 1) The specimen is received fresh, labeled "Left Kidney and Adrenal Gland". It consists of a product of left nephrectomy consisting of a left kidney, fragment of renal blood vessel, fragment of a ureter, and adrenal gland surrounded by perinephric adipose tissue weighing 460 grams. The kidney measures 10.5 x 8 x 4.5 cm. The fragment of ureter measures 6 cm in length and 0.4 cm in diameter. The Gerota's fascia is inked. Upon bivalving, a large, lobulated, focally hemorrhagic, pink-orange mass is present superiorly to the kidney within the perinephric adipose tissue abutting Gerota's fascia. The mass measures 10.5 x 10 x 2 cm. There is approximately 20% necrosis present. On serial sectioning, the mass completely replaces the adrenal gland parenchyma. The mass is extrarenal. Situated at the lower pole of the kidney is a subcapsular, pink-yellow, centrally necrotic tumor measuring 5.5 x 4.5 x 3 cm. Grossly, no extracapsular invasion is identified. The tumor is situated 1 cm from the Gerota's fascia. There is a satellite tumor nodule identified within the lumen of the blood vessel. No tumor is present at the surgical margin of the renal blood vessels. Noted is a tumor nodule at the hilar region of the kidney, extending into the perinephric adipose tissue. Grossly, the collecting system is unremarkable. The urothelium of the renal pelvis and ureter is thin and smooth. The rest of the renal parenchyma is unremarkable. The subcortical surface of the kidney is smooth. No lymph nodes are identified at

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

the hilar region of the kidney. Tumor is submitted for TPS and EM. Photographs are taken. Representative sections are submitted.

Summary of Sections:

USM -- urethral surgical margin
VSM -- vascular surgical margin
AT -- adrenal tumor
RTC -- renal tumor in relation to capsule
RTK -- renal tumor in relation to kidney
RT -- renal tumor
THR -- renal tumor at the hilar region
TBV -- tumor within the lumen of the blood vessel
UK -- unremarkable kidney.

Summary of Sections:

Part 1: SP: Lt. kidney & adrenal gland

Block	Sect. Site	PCs
8	AT	8
3	RT	3
3	RTC	3
1	RTK	1
1	TBV	1
1	THR	1
1	UK	1
1	USM	1
1	VSM	3

Source: NCI Genomic Data Commons file 2be2db7f-f71e-415f-8431-887051a169ec (TCGA-BP-4335.1F751DB1-778F-4E9B-897C-CC110AB3C374.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).